Somatic mutation profile of tumor specimen C3N-00549-03 (aliquot CPT0067450006) from CPTAC case C3N-00549, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.6 years (21,402 days).
Specimen C3N-00549-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 132706f3-dff5-474a-a049-9ee24dc030ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00549-71 (Blood Derived Normal), aliquot CPT0067550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a07404f-6619-4742-b977-27ffebab9a13

The open-access MAF lists 527 somatic variants for this specimen: 383 protein-altering or splice-affecting, 94 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 94, Nonsense Mutation 26, Intron 24, Splice Site 13, Frame Shift Del 12, RNA 10, 3'UTR 6, 5'Flank 5, Splice Region 5, Frame Shift Ins 4, 5'UTR 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 114/362 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 122/308 reads (40%) | catalogued as rs1567556752, CM120852, COSV52811974, COSV52991347; ClinVar: pathogenic; called by muse, mutect2
- ABCA13 | c.11152G>T p.A3718S | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV71285284; called by muse, mutect2, varscan2
- ACTN3 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 108/305 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1490104628; called by muse, mutect2, varscan2
- ADAMTSL5 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57861184; called by muse, mutect2, varscan2
- ADCY1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs369079165, COSV52030947; called by muse, mutect2, varscan2
- ADGB | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373227451; called by muse, mutect2, varscan2
- ANK1 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 260/616 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV55872662; called by muse, mutect2, varscan2
- AP4M1 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 236/434 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs773269627, COSV100385147; called by muse, mutect2, varscan2
- ASTN2 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 93/122 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV57770911; called by muse, mutect2, varscan2
- ASXL1 | c.2210T>G p.V737G | Missense Mutation (SNP) | VAF 155/563 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV60122404; called by muse, mutect2, varscan2
- ATF5 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61312162; called by muse, mutect2, varscan2
- ATXN7L2 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs756728202; called by muse, mutect2, varscan2
- AVPR2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 134/163 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100509715; called by muse, mutect2, varscan2
- BGN | c.312G>C p.E104D | Missense Mutation (SNP) | VAF 102/123 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782533603; called by muse, mutect2, varscan2
- BRINP3 | c.1445C>A p.T482N | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV100818683, COSV66528963; called by muse, mutect2, varscan2
- C17orf50 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1555602201; called by muse, mutect2, varscan2
- CACNA1E | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV62405927, COSV62425336; called by muse, mutect2, varscan2
- CC2D2A | c.1846C>G p.L616V | Missense Mutation (SNP) | VAF 113/153 reads (74%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs1560171700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD83 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as COSV64788363; called by muse, mutect2, varscan2
- CDKL4 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs780414961; called by muse, mutect2, varscan2
- CFHR5 | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1291068959; called by muse, mutect2, varscan2
- CLPTM1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 83/150 reads (55%) | catalogued as COSV61611687; called by muse, mutect2, varscan2
- CNBD1 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs367898641; called by muse, mutect2, varscan2
- COL22A1 | c.2755-1G>T p.X919_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57346059; called by muse, mutect2, varscan2
- CSH2 | c.642C>A p.S214R | Missense Mutation (SNP) | VAF 167/402 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1277114376; called by muse, mutect2, varscan2
- CXADR | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53027863; called by muse, mutect2, varscan2
- DENND2A | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.313); catalogued as COSV52057267; called by muse, mutect2, varscan2
- DENND4B | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 157/372 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369509739; called by muse, mutect2, varscan2
- DLGAP2 | c.1112G>C p.W371S | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV70097201; called by muse, mutect2, varscan2
- DSC1 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 81/120 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs773770610, COSV57148047; called by muse, mutect2, varscan2
- DYNC1H1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 137/273 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs1488184652, COSV64141425; called by muse, mutect2, varscan2
- E2F7 | c.79del p.E27Kfs*21 | Frame Shift Del (DEL) | VAF 76/273 reads (28%) | catalogued as COSV59738085; called by mutect2, pindel, varscan2
- EMILIN1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs777527430, COSV66695549; called by muse, mutect2, varscan2
- FAM170A | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 104/160 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100089336; called by muse, mutect2, varscan2
- FAM71A | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1558246478; called by muse, mutect2, varscan2
- FLG | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 286/706 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV64244057; called by muse, mutect2, varscan2
- FRMD4B | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV68330445; called by muse, mutect2, varscan2
- GATA6 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 69/94 reads (73%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.918); catalogued as rs1435712434; called by muse, mutect2, varscan2
- GMNC | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1231082884; called by muse, mutect2, varscan2
- GRM5 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV59632326; called by muse, mutect2, varscan2
- H2BC13 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV62440389; called by muse, mutect2, varscan2
- HERC1 | c.8297A>C p.Q2766P | Missense Mutation (SNP) | VAF 113/201 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV71246067; called by muse, mutect2, varscan2
- HMGCLL1 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51440751; called by muse, mutect2, varscan2
- HMX2 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 181/363 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1392622657; called by muse, mutect2, varscan2
- HOXC4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs769799395; called by muse, mutect2, varscan2
- HRNR | c.2623C>A p.H875N | Missense Mutation (SNP) | VAF 167/397 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs140521585; called by muse, mutect2, varscan2
- ITGA4 | c.3008G>A p.G1003D | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59207420; called by muse, mutect2, varscan2
- ITGA8 | c.1903-1G>T p.X635_splice | Splice Site (SNP) | VAF 36/140 reads (26%) | catalogued as COSV100959122; called by muse, mutect2, varscan2
- ITGA8 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65232864; called by muse, mutect2, varscan2
- ITGBL1 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66011871; called by muse, mutect2, varscan2
- KRT17 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 307/760 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs747955715, COSV60861619; called by muse, mutect2, varscan2
- LAMB4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1199544670; called by muse, varscan2
- LGALS9C | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs763525726; called by muse, mutect2
- LIPC | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 136/602 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs775782543; called by muse, mutect2
- LMOD2 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs372234002; called by muse, mutect2, varscan2
- MMP25 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV60678996; called by muse, mutect2, varscan2
- MSRB3 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57587729; called by muse, mutect2, varscan2
- MUC5AC | c.14959C>A p.R4987S | Missense Mutation (SNP) | VAF 171/222 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs781049302, COSV64369953; called by muse, mutect2, varscan2
- NCKAP5 | c.3761C>A p.S1254Y | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100493376; called by muse, mutect2, varscan2
- NCOA2 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1326252258; called by muse, varscan2
- NCOR2 | c.6653G>T p.G2218V | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as rs779205903, COSV100657707; called by muse, mutect2, varscan2
- NF1 | c.3151G>T p.G1051* | Nonsense Mutation (SNP) | VAF 117/305 reads (38%) | catalogued as CD982826; called by muse, mutect2, varscan2
- NFATC4 | c.1568G>A p.C523Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372251932; called by muse, mutect2
- NLRC5 | c.4091G>A p.G1364D | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs766354961; called by muse, mutect2, varscan2
- NOD2 | c.2729G>T p.R910I | Missense Mutation (SNP) | VAF 175/412 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1354091032; called by muse, mutect2, varscan2
- NOL10 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV62042406; called by muse, mutect2, varscan2
- NPAP1 | c.2786C>A p.T929K | Missense Mutation (SNP) | VAF 211/403 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV61503925; called by muse, mutect2, varscan2
- NRN1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV99784326; called by muse, mutect2, varscan2
- NRXN1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs201566733, COSV68006810; called by muse, mutect2, varscan2
- NRXN2 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1159935878, COSV55449991; called by muse, mutect2, varscan2
- OPRL1 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV100402192; called by muse, mutect2, varscan2
- OR10J3 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59954400; called by muse, mutect2, varscan2
- OR10J3 | c.540T>A p.C180* | Nonsense Mutation (SNP) | VAF 116/280 reads (41%) | catalogued as COSV59953646; called by muse, mutect2, varscan2
- OR10W1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs200070425, COSV67720621; called by muse, mutect2, varscan2
- OR13C8 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 94/129 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1323175968, COSV58611081; called by muse, mutect2, varscan2
- OR51B2 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 65/92 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV60916397; called by muse, varscan2
- OR8J3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100040895, COSV56880985; called by muse, mutect2, varscan2
- PCDHGB3 | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs966537546; called by muse, mutect2, varscan2
- PF4V1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as rs752058536; called by muse, mutect2, varscan2
- POU6F2 | c.1083C>G p.S361R | Missense Mutation (SNP) | VAF 143/470 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV68872206; called by muse, mutect2, varscan2
- PRPF4B | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 150/378 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs752566840; called by muse, mutect2, varscan2
- PSAT1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 210/305 reads (69%) | catalogued as COSV61303917; called by muse, mutect2, varscan2
- PTPRT | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62012566; called by muse, mutect2, varscan2
- RANBP10 | c.1177G>C p.V393L | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV58157678, COSV58157767; called by muse, varscan2
- RIMS3 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV65504357; called by muse, mutect2, varscan2
- RPAP3 | c.294+1G>A p.X98_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as rs1038539249; called by muse, mutect2
- RYR2 | c.2542C>A p.R848S | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV100772577, COSV63674230; called by muse, mutect2, varscan2
- RYR2 | c.3641G>T p.R1214M | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100771402; called by muse, mutect2, varscan2
- SEL1L | c.69G>T p.S23= | Splice Region (SNP) | VAF 116/208 reads (56%) | catalogued as rs1408122650; called by muse, varscan2
- SEMA5A | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221069422, COSV66806542; called by muse, mutect2
- SHKBP1 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52538099; called by muse, mutect2, varscan2
- SIGLEC12 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as rs143800743; called by muse, mutect2, varscan2
- SLC25A53 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62458639; called by muse, mutect2, varscan2
- SLC5A7 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV50902580; called by muse, mutect2, varscan2
- SLC7A5 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 414/880 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188786744; called by muse, mutect2, varscan2
- SLITRK2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 112/133 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373498501, COSV59428955; called by muse, mutect2, varscan2
- SNRPF | c.4-1G>T p.X2_splice | Splice Site (SNP) | VAF 56/158 reads (35%) | catalogued as COSV99900056, COSV99900077; called by muse, varscan2
- SORCS3 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1321795308; called by muse, mutect2, varscan2
- SPATA19 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100141010; called by muse, mutect2, varscan2
- SPDYE4 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV60906080; called by muse, mutect2, varscan2
- SPEN | c.5344G>T p.D1782Y | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV101005710; called by muse, mutect2, varscan2
- SRCIN1 | c.3170G>A p.R1057H (on ENST00000621492; = p.R1023H on NM_025248.3) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753640745; called by muse, mutect2, varscan2
- STK11 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 136/182 reads (75%) | catalogued as COSV58827752; called by muse, mutect2, varscan2
- SUMF1 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 131/210 reads (62%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55994121; called by muse, mutect2, varscan2
- TCN1 | c.1299C>A p.Y433* | Nonsense Mutation (SNP) | VAF 201/543 reads (37%) | catalogued as COSV57254210; called by muse, mutect2, varscan2
- TECTA | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760011660, COSV50687716; called by muse, mutect2
- TLN2 | c.6604G>T p.V2202L | Missense Mutation (SNP) | VAF 130/239 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV60895390; called by muse, mutect2, varscan2
- TLR4 | c.2047C>A p.Q683K (on ENST00000355622 / NM_138554.5; = p.Q643K on NM_003266.4) | Missense Mutation (SNP) | VAF 63/97 reads (65%) | SIFT tolerated (0.8); PolyPhen benign (0.041); catalogued as COSV100842651; called by muse, mutect2, varscan2
- TMPRSS11B | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219327; called by muse, mutect2, varscan2
- TNFRSF11B | c.585T>A p.C195* | Nonsense Mutation (SNP) | VAF 12/368 reads (3%) | catalogued as COSV52072171; called by muse, mutect2
- TRPM4 | c.2675G>C p.R892P | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53259954; called by muse, mutect2, varscan2
- TUBD1 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV57873537; called by muse, mutect2, varscan2
- UGT1A8 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 122/176 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1210754618; called by muse, mutect2, varscan2
- USH2A | c.14676G>T p.Q4892H | Missense Mutation (SNP) | VAF 182/528 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1289916931; called by muse, mutect2, varscan2
- ZDBF2 | c.3280dup p.I1094Nfs*14 | Frame Shift Ins (INS) | VAF 21/66 reads (32%) | catalogued as rs765952396; called by mutect2, varscan2
- ZFHX4 | c.8610C>G p.S2870R | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50663370; called by muse, mutect2, varscan2
- ZNF215 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs753451888; called by muse, mutect2, varscan2
- ZNF30 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779657296; called by muse, mutect2, varscan2
- ZNF667 | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.339); catalogued as rs369277584; called by muse, mutect2, varscan2
- ZNF786 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs757993929; called by muse, mutect2, varscan2
- ABCB8 | c.979-2A>T p.X327_splice (on ENST00000297504 / NM_001282291.2; = p.X310_splice on NM_007188.5) | Splice Site (SNP) | VAF 115/234 reads (49%) | called by muse, mutect2, varscan2
- ABCC3 | c.4491C>A p.D1497E | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, varscan2
- ACAN | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 117/199 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ACSM2A | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADAMTS12 | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGXT2 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AHCYL1 | c.1053-1G>T p.X351_splice | Splice Site (SNP) | VAF 77/216 reads (36%) | called by muse, mutect2, varscan2
- AHNAK2 | c.11647A>T p.K3883* | Nonsense Mutation (SNP) | VAF 219/425 reads (52%) | called by muse, mutect2, varscan2
- AKR1B15 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 52/107 reads (49%) | PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ALKBH8 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ALOXE3 | c.1046del p.P349Hfs*99 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- ANK2 | c.3650_3651insA p.S1217Rfs*9 | Frame Shift Ins (INS) | VAF 139/238 reads (58%) | called by mutect2, pindel*, varscan2
- ANK2 | c.5053G>T p.D1685Y | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ANK2 | c.10077G>T p.Q3359H | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ANKRD30A | c.3205C>A p.L1069I (on ENST00000611781; = p.L1013I on NM_052997.2) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ANO1 | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 99/260 reads (38%) | called by muse, mutect2, varscan2
- ANPEP | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- APC | c.3517G>T p.V1173L | Missense Mutation (SNP) | VAF 142/235 reads (60%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- APH1B | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGEF4 | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.041); called by muse, varscan2
- ARID1B | c.1823del p.P608Rfs*47 | Frame Shift Del (DEL) | VAF 138/414 reads (33%) | called by mutect2, pindel, varscan2
- ART5 | c.819A>T p.P273= | Splice Region (SNP) | VAF 91/131 reads (69%) | called by muse, mutect2, varscan2
- ASXL2 | c.2932A>G p.K978E | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ATP2B3 | c.643del p.D215Tfs*30 | Frame Shift Del (DEL) | VAF 87/131 reads (66%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- BCAS1 | c.227dup p.N76Kfs*17 | Frame Shift Ins (INS) | VAF 155/338 reads (46%) | called by mutect2, pindel, varscan2
- BHLHE41 | c.165A>T p.K55N | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD2 | c.913_918dup p.S305_L306dup | In Frame Ins (INS) | VAF 66/196 reads (34%) | called by mutect2, pindel, varscan2
- C14orf180 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.2756C>A p.T919K | Missense Mutation (SNP) | VAF 79/122 reads (65%) | SIFT tolerated (0.83); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CACNG1 | c.482C>A p.S161* | Nonsense Mutation (SNP) | VAF 129/241 reads (54%) | called by muse, mutect2, varscan2
- CAND1 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARMIL3 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CBX2 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 199/575 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCDC166 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC168 | c.5837A>T p.Q1946L | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- CCDC61 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CDH19 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 107/154 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH8 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3194G>T p.C1065F | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CEBPB | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 137/241 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP128 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CEP192 | c.6608A>T p.Q2203L | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CEP290 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CFAP44 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 109/184 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CFAP47 | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 133/181 reads (73%) | SIFT tolerated (0.63); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CFAP74 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.56); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CFAP94 | c.440T>G p.F147C (on ENST00000320267 / NM_001352064.2; = p.F153C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHAT | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 242/476 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CHD7 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, varscan2
- CNTN5 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CNTN5 | c.3137G>C p.R1046P | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CNTNAP2 | c.2813G>T p.R938L | Missense Mutation (SNP) | VAF 197/370 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL16A1 | c.2562G>C p.Q854H | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- COL5A1 | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 252/366 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CPA1 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSGALNACT1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSMD2 | c.7279C>A p.L2427I | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CYP4V2 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 150/199 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DAB2 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DDX39B | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DEGS1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 94/231 reads (41%) | called by muse, mutect2, varscan2
- DHX9 | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- DNAJC10 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- DPY19L1 | c.1746-2A>T p.X582_splice | Splice Site (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- DPYSL3 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 96/113 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC2H1 | c.4328A>T p.Q1443L | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECT2 | c.433G>C p.D145H (on ENST00000392692 / NM_001349098.2; = p.D114H on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- EEF1A2 | c.860C>A p.T287N | Missense Mutation (SNP) | VAF 346/629 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EFCAB5 | c.2719A>T p.K907* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- EGR3 | c.998T>A p.F333Y | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF1AD | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF5A | c.50C>G p.T17S | Missense Mutation (SNP) | VAF 203/533 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ENO3 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 253/682 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- EPHA5 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ERICH3 | c.2115G>C p.W705C | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM131A | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM136A | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM43A | c.872_889del p.P291_E297delinsQ | In Frame Del (DEL) | VAF 29/53 reads (55%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.589+1G>T p.X197_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- FANCM | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FGD2 | c.1919C>A p.A640D | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, varscan2
- FGF3 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGR | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 87/132 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG | c.7906G>T p.G2636C | Missense Mutation (SNP) | VAF 144/718 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, varscan2
- FLG | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 239/608 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- FREM3 | c.4916C>A p.A1639D | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FREM3 | c.4915G>A p.A1639T | Missense Mutation (SNP) | VAF 108/154 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FRMPD1 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 100/147 reads (68%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRR2 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GC | c.955del p.Q319Nfs*8 | Frame Shift Del (DEL) | VAF 183/425 reads (43%) | called by mutect2, pindel, varscan2
- GLCCI1 | c.698A>T p.Q233L | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GLRA4 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 130/162 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- GLT6D1 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMCL2 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 293/362 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GMFB | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GOLGA2 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GOLGA8H | c.1878G>A p.W626* | Nonsense Mutation (SNP) | VAF 343/654 reads (52%) | called by muse, mutect2, varscan2
- GOLGA8J | c.1734G>T p.E578D | Missense Mutation (SNP) | VAF 139/259 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by mutect2, varscan2
- GPER1 | c.674T>G p.V225G | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- GPR152 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR78 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GRIN1 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 260/377 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYPB | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 172/283 reads (61%) | called by muse, mutect2, varscan2
- H2BC21 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 205/567 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HAL | c.1258A>T p.T420S | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HAVCR1 | c.379+1G>T p.X127_splice | Splice Site (SNP) | VAF 28/34 reads (82%) | called by muse, mutect2, varscan2
- HCN1 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- HOXC4 | c.233C>G p.S78W | Missense Mutation (SNP) | VAF 245/484 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- IGSF1 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IL20RA | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ITGAM | c.2390G>T p.G797V (on ENST00000648685 / NM_001145808.2; = p.G796V on NM_000632.4) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ITPK1 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- JAKMIP1 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 107/166 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- KCNH6 | c.2020G>T p.V674L | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KCP | c.2898G>T p.E966D (on ENST00000620378; = p.E1026D on NM_001366122.1) | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDR | c.1718C>A p.A573E | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KDR | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- KIAA2012 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- KIR2DS4 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KLK10 | c.589A>T p.S197C | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KPRP | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KRT1 | c.1849G>T p.G617* | Nonsense Mutation (SNP) | VAF 335/688 reads (49%) | called by muse, mutect2, varscan2
- KRTAP6-3 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 51/222 reads (23%) | PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- LCTL | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 97/150 reads (65%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LOXHD1 | c.2586G>C p.K862N | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LPA | c.4282C>A p.P1428T | Missense Mutation (SNP) | VAF 141/367 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- LPIN3 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LRRC28 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT tolerated (0.62); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MAP2 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, varscan2
- MARCKS | c.837_838del p.C279* | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel
- MASP1 | c.1742del p.G581Efs*21 | Frame Shift Del (DEL) | VAF 213/360 reads (59%) | called by mutect2, pindel, varscan2
- MATR3 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MIOS | c.1426G>T p.G476W | Missense Mutation (SNP) | VAF 94/173 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, varscan2
- MKI67 | c.8129del p.P2710Hfs*2 | Frame Shift Del (DEL) | VAF 165/425 reads (39%) | called by mutect2, pindel, varscan2
- MKI67 | c.6757_6774del p.L2253_R2258del | In Frame Del (DEL) | VAF 177/516 reads (34%) | called by mutect2, pindel, varscan2
- MLH3 | c.3353G>T p.R1118M | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MRGPRX2 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 76/108 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MS4A4E | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MS4A4E | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.7434G>T p.W2478C | Missense Mutation (SNP) | VAF 104/133 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYEOV | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MYF5 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH1 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- N6AMT1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NANOS1 | c.276_307del p.P93Rfs*236 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- NCKAP5 | c.2636C>A p.P879H | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NEDD4L | c.2171G>T p.G724V (on ENST00000400345 / NM_001144967.3; = p.G704V on NM_015277.6) | Missense Mutation (SNP) | VAF 86/117 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NES | c.3635A>G p.E1212G | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEUROD6 | c.315C>A p.N105K | Missense Mutation (SNP) | VAF 142/434 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- NLRP3 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 227/608 reads (37%) | called by muse, mutect2, varscan2
- NMNAT2 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NPC1L1 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NSMF | c.1333A>T p.S445C (on ENST00000371475 / NM_001130969.3; = p.S443C on NM_015537.4) | Missense Mutation (SNP) | VAF 148/201 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NSUN6 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NT5DC4 | c.734G>C p.W245S | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR14C36 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR1Q1 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 62/103 reads (60%) | called by muse, mutect2, varscan2
- OR2H1 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2L8 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 138/401 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- OR4A15 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR52E8 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5AP2 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OR5H15 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 110/181 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OTOGL | c.1295T>C p.M432T (on ENST00000547103; = p.M423T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- OTUD7B | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTX1 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PATJ | c.3853G>T p.D1285Y | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PAX7 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCARE | c.2228G>T p.S743I | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- PCDH15 | c.2285T>G p.L762R | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCDHGA4 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- PHRF1 | c.2278G>T p.A760S (on ENST00000264555 / NM_001286581.2; = p.A759S on NM_020901.4) | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT tolerated (0.75); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PLA2R1 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMS1 | c.852C>G p.C284W | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- POU6F2 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 290/478 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PPIL2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKAG2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 158/309 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PRKD1 | c.2415G>T p.W805C | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXDN | c.2270G>T p.G757V | Missense Mutation (SNP) | VAF 191/455 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PZP | c.2261C>A p.S754* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | called by muse, varscan2
- RAB3GAP2 | c.485C>A p.S162* | Nonsense Mutation (SNP) | VAF 244/644 reads (38%) | called by muse, mutect2, varscan2
- RAD51AP1 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RANBP9 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RAP1GAP2 | c.100A>T p.S34C | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- RAPSN | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 147/223 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- RASGEF1B | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBMX2 | c.516del p.E173Rfs*22 | Frame Shift Del (DEL) | VAF 48/78 reads (62%) | called by mutect2, pindel, varscan2
- RELN | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 123/484 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROBO3 | c.3795G>T p.G1265= | Splice Region (SNP) | VAF 81/230 reads (35%) | called by muse, mutect2, varscan2
- RUNDC3B | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- S1PR5 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 101/136 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMD3 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 152/408 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SAMD4A | c.1323G>T p.M441I | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD8 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 67/247 reads (27%) | called by muse, mutect2, varscan2
- SEMA5A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEPTIN14 | c.659T>A p.I220N | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SERPINB2 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SETD1B | c.5463G>T p.Q1821H | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC14 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIN3B | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 122/173 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SLC29A2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 114/379 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC35F1 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SLC3A1 | c.1332+1del | Frame Shift Del (DEL) | VAF 136/394 reads (35%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.1498G>T p.D500Y (on ENST00000446997 / NM_001354461.2; = p.D470Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/107 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A2 | c.2124C>A p.C708* | Nonsense Mutation (SNP) | VAF 131/283 reads (46%) | called by muse, mutect2, varscan2
- SLC5A8 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SLC6A5 | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 203/321 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SMARCC1 | c.3137G>T p.S1046I | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, varscan2
- SMG1 | c.5461+1G>T p.X1821_splice | Splice Site (SNP) | VAF 60/137 reads (44%) | called by muse, varscan2
- SMIM23 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 284/371 reads (77%) | called by muse, mutect2, varscan2
- SNAP91 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- SON | c.6939G>T p.M2313I | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SP140 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SPATA31A1 | c.2549G>T p.G850V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- SPEG | c.1300C>A p.R434S | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SSH1 | c.922A>T p.K308* | Nonsense Mutation (SNP) | VAF 75/264 reads (28%) | called by muse, varscan2
- STAG1 | c.885A>G p.I295M | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SUCLG1 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 217/574 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SUPT5H | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TENM4 | c.5496G>T p.R1832= | Splice Region (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- TEX35 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFAP2A | c.788G>T p.G263V (on ENST00000482890; = p.G255V on NM_001032280.3) | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLNRD1 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- TMEM260 | c.40C>G p.H14D | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated, low confidence (0.31); called by muse, mutect2
- TRABD2A | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV20-1 | c.295C>A p.H99N | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.195); called by muse, varscan2
- TRHDE | c.7del p.E3? | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by pindel, varscan2
- TRIM64 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM9 | c.1942G>T p.G648W | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRO | c.3674C>A p.T1225N | Missense Mutation (SNP) | VAF 110/137 reads (80%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TSHZ2 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 92/170 reads (54%) | called by muse, mutect2, varscan2
- UBE4A | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBR1 | c.3504G>T p.W1168C | Missense Mutation (SNP) | VAF 162/658 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- UNC45A | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 207/316 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTRN | c.3679A>G p.T1227A | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VAV3 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- VCAN | c.2942C>G p.T981R | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- VIT | c.802+2T>A p.X268_splice | Splice Site (SNP) | VAF 61/160 reads (38%) | called by muse, mutect2, varscan2
- VN1R2 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VSNL1 | c.180C>A p.D60E | Missense Mutation (SNP) | VAF 126/286 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- VWC2L | c.489dup p.P164Tfs*26 | Frame Shift Ins (INS) | VAF 61/135 reads (45%) | called by pindel, varscan2
- VWC2L | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, varscan2
- WASHC2C | c.3251G>T p.R1084I (on ENST00000336378; = p.R1063I on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 434/866 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZBED9 | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H4 | c.870+1G>T p.X290_splice | Splice Site (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10799C>T p.S3600F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZFP90 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF142 | c.4683G>T p.E1561D (on ENST00000411696 / NM_001379660.1; = p.E1361D on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF232 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF37A | c.144G>T p.G48= | Splice Region (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- ZNF469 | c.11644G>T p.A3882S (on ENST00000437464; = p.A3910S on NM_001367624.2) | Missense Mutation (SNP) | VAF 207/418 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF528 | c.976A>T p.S326C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF536 | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF616 | c.973T>G p.F325V | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- ZNF616 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 165/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF677 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.287); called by muse, varscan2
- ZNF71 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF813 | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ZZZ3 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- AC005833.1 | c.1638C>A p.T546= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as rs754313858; called by muse, mutect2, varscan2
- ADAMTSL5 | c.945G>C p.L315= | Silent (SNP) | VAF 20/26 reads (77%) | called by muse, mutect2, varscan2
- ADAR | c.3144G>T p.L1048= | Silent (SNP) | VAF 175/384 reads (46%) | called by muse, mutect2, varscan2
- ADGRA2 | c.51G>T p.L17= | Silent (SNP) | VAF 18/29 reads (62%) | called by muse, varscan2
- ARHGAP17 | c.1425G>T p.G475= | Silent (SNP) | VAF 78/219 reads (36%) | called by muse, mutect2, varscan2
- ASXL2 | c.2037A>C p.A679= | Silent (SNP) | VAF 111/256 reads (43%) | called by muse, mutect2, varscan2
- ATG7 | c.2106C>A p.T702= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as COSV99809888; called by muse, mutect2, varscan2
- ATP6V1H | c.895A>C p.R299= | Silent (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- BCAN | c.384C>A p.R128= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV100228510; called by muse, mutect2, varscan2
- BRPF3 | c.1005A>T p.A335= | Silent (SNP) | VAF 120/315 reads (38%) | called by muse, mutect2, varscan2
- C11orf42 | c.894C>A p.R298= | Silent (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- C17orf50 | c.264G>A p.A88= | Silent (SNP) | VAF 91/224 reads (41%) | called by muse, mutect2, varscan2
- C6 | c.1965C>A p.I655= | Silent (SNP) | VAF 124/367 reads (34%) | catalogued as COSV54705476, COSV54708392; called by muse, mutect2, varscan2
- CAND1 | c.1575G>T p.V525= | Silent (SNP) | VAF 52/273 reads (19%) | called by muse, mutect2, varscan2
- CARD6 | c.2532A>G p.A844= | Silent (SNP) | VAF 110/308 reads (36%) | called by muse, mutect2, varscan2
- CEP128 | c.405G>T p.G135= | Silent (SNP) | VAF 26/177 reads (15%) | catalogued as COSV99383136; called by muse, mutect2, varscan2
- CFAP65 | c.1431C>A p.V477= | Silent (SNP) | VAF 92/119 reads (77%) | called by muse, mutect2, varscan2
- CFAP69 | c.1929A>T p.A643= | Silent (SNP) | VAF 78/171 reads (46%) | called by muse, mutect2, varscan2
- COL9A3 | c.999C>T p.N333= | Silent (SNP) | VAF 121/457 reads (26%) | catalogued as rs531882222; called by muse, mutect2, varscan2
- CPA4 | c.1011T>A p.L337= | Silent (SNP) | VAF 95/188 reads (51%) | called by muse, mutect2, varscan2
- CSMD2 | c.8622C>G p.T2874= | Silent (SNP) | VAF 81/113 reads (72%) | called by muse, mutect2, varscan2
- CSMD2 | c.7278C>A p.A2426= | Silent (SNP) | VAF 59/92 reads (64%) | called by muse, varscan2
- CSMD3 | c.4623G>T p.G1541= (on ENST00000297405 / NM_001363185.1; = p.G1437= on NM_052900.3) | Silent (SNP) | VAF 109/262 reads (42%) | catalogued as COSV52240105; called by muse, mutect2, varscan2
- CSMD3 | c.969C>A p.L323= | Silent (SNP) | VAF 112/268 reads (42%) | catalogued as COSV99851148; called by muse, mutect2, varscan2
- CUX1 | c.1776G>T p.R592= | Silent (SNP) | VAF 187/371 reads (50%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.957C>A p.P319= | Silent (SNP) | VAF 90/218 reads (41%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1863C>A p.T621= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs920934747; called by muse, mutect2, varscan2
- DSCAML1 | c.3504C>A p.V1168= (on ENST00000321322; = p.V1108= on NM_020693.4) | Silent (SNP) | VAF 75/238 reads (32%) | catalogued as rs148707112; called by muse, mutect2, varscan2
- DUSP22 | c.288G>T p.V96= | Silent (SNP) | VAF 54/260 reads (21%) | catalogued as COSV100739773; called by muse, varscan2
- F13A1 | c.1485A>T p.L495= | Silent (SNP) | VAF 159/366 reads (43%) | called by muse, mutect2, varscan2
- FAM71F2 | c.639C>T p.S213= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1055874739; called by muse, mutect2, varscan2
- FERD3L | c.69C>A p.A23= | Silent (SNP) | VAF 65/224 reads (29%) | catalogued as COSV51762468; called by muse, mutect2, varscan2
- FLG2 | c.6540C>T p.H2180= | Silent (SNP) | VAF 83/218 reads (38%) | called by muse, mutect2, varscan2
- GIMAP8 | c.540C>A p.T180= | Silent (SNP) | VAF 69/248 reads (28%) | called by muse, mutect2, varscan2
- GRIN2A | c.2694C>A p.L898= | Silent (SNP) | VAF 182/527 reads (35%) | called by muse, mutect2, varscan2
- GRK1 | c.1140C>G p.V380= | Silent (SNP) | VAF 99/158 reads (63%) | called by muse, mutect2, varscan2
- GTSE1 | c.1263C>A p.P421= | Silent (SNP) | VAF 78/125 reads (62%) | catalogued as rs373959629; called by muse, mutect2, varscan2
- HDAC9 | c.114C>T p.D38= | Silent (SNP) | VAF 154/618 reads (25%) | catalogued as COSV67774999; called by muse, varscan2
- HRNR | c.2622C>A p.S874= | Silent (SNP) | VAF 163/392 reads (42%) | catalogued as rs745354816; called by muse, mutect2, varscan2
- HRNR | c.723C>T p.S241= | Silent (SNP) | VAF 239/570 reads (42%) | called by muse, mutect2, varscan2
- HSPBP1 | c.546G>A p.Q182= | Silent (SNP) | VAF 93/327 reads (28%) | called by muse, mutect2, varscan2
- HTR5A | c.129T>A p.I43= | Silent (SNP) | VAF 127/255 reads (50%) | called by muse, mutect2, varscan2
- HYDIN | c.3216C>T p.Y1072= | Silent (SNP) | VAF 71/230 reads (31%) | catalogued as rs1302603620, COSV66833099; called by muse, mutect2, varscan2
- KCNQ5 | c.2322G>A p.Q774= | Silent (SNP) | VAF 156/243 reads (64%) | called by muse, mutect2, varscan2
- KIF13A | c.3642G>A p.L1214= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- KLK10 | c.588G>A p.L196= | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- LCE1C | c.105T>A p.P35= | Silent (SNP) | VAF 155/414 reads (37%) | catalogued as COSV64218107; called by muse, mutect2, varscan2
- LILRB2 | c.426C>A p.L142= | Silent (SNP) | VAF 112/229 reads (49%) | called by muse, mutect2, varscan2
- MARCKS | c.435G>A p.S145= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV64043464; called by muse, mutect2, varscan2
- MGAT3 | c.582C>A p.P194= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as rs760637863; called by muse, mutect2, varscan2
- MGAT5B | c.1131C>T p.H377= | Silent (SNP) | VAF 91/199 reads (46%) | called by muse, mutect2, varscan2
- MIER1 | c.1494A>T p.A498= (on ENST00000355356 / NM_001077701.3; = p.A515= on NM_020948.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/77 reads (69%) | catalogued as COSV100590814; called by muse, mutect2, varscan2
- MNAT1 | c.735G>T p.L245= | Silent (SNP) | VAF 77/187 reads (41%) | called by muse, mutect2, varscan2
- MYH10 | c.5628C>T p.N1876= | Silent (SNP) | VAF 69/159 reads (43%) | catalogued as rs145331684; called by muse, mutect2, varscan2
- MYLK4 | c.867G>T p.V289= | Silent (SNP) | VAF 100/217 reads (46%) | called by muse, mutect2, varscan2
- MYO7B | c.3384C>A p.A1128= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- NACAD | c.474G>A p.Q158= | Silent (SNP) | VAF 52/134 reads (39%) | called by muse, mutect2, varscan2
- NCKAP1L | c.702C>G p.P234= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as rs760116643; called by muse, mutect2, varscan2
- NLRP2 | c.2235G>C p.R745= | Silent (SNP) | VAF 203/443 reads (46%) | catalogued as COSV54757618; called by muse, mutect2, varscan2
- NLRP4 | c.1170G>T p.P390= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as rs147261455; called by muse, mutect2, varscan2
- NPAP1 | c.2991G>C p.L997= | Silent (SNP) | VAF 87/347 reads (25%) | catalogued as COSV61505072, COSV61510493; called by muse, mutect2, varscan2
- NXPH4 | c.340C>A p.R114= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs771787024; called by muse, mutect2, varscan2
- OPRM1 | c.183G>T p.P61= | Silent (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
- OR2AK2 | c.600C>A p.L200= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV63560963; called by muse, mutect2, varscan2
- OR2B11 | c.186C>A p.P62= | Silent (SNP) | VAF 120/252 reads (48%) | catalogued as COSV59509548, COSV59510563; called by muse, mutect2, varscan2
- OR4P4 | c.378G>A p.K126= | Silent (SNP) | VAF 59/72 reads (82%) | catalogued as rs1213483798; called by muse, mutect2, varscan2
- OR5B21 | c.72C>T p.P24= | Silent (SNP) | VAF 83/196 reads (42%) | catalogued as COSV64482255; called by muse, mutect2, varscan2
- OR6C4 | c.186G>T p.R62= | Silent (SNP) | VAF 66/153 reads (43%) | catalogued as COSV101263133; called by muse, mutect2, varscan2
- OR8I2 | c.732C>A p.L244= | Silent (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- PAIP1 | c.279C>T p.P93= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs757134803, COSV59086147; called by muse, mutect2, varscan2
- PCNX2 | c.1944C>T p.T648= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as rs779384633; called by muse, mutect2, varscan2
- PDE1C | c.819C>A p.T273= | Silent (SNP) | VAF 98/458 reads (21%) | catalogued as COSV58512212; called by muse, mutect2, varscan2
- PIK3C2A | c.3858G>T p.R1286= | Silent (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- PKP2 | c.51G>T p.L17= | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- PNMA5 | c.369C>G p.A123= | Silent (SNP) | VAF 28/32 reads (88%) | called by muse, mutect2, varscan2
- PRSS23 | c.906T>C p.Y302= | Silent (SNP) | VAF 130/302 reads (43%) | catalogued as rs745498382; called by muse, mutect2, varscan2
- RARG | c.381C>T p.H127= | Silent (SNP) | VAF 102/306 reads (33%) | called by muse, mutect2, varscan2
- RELN | c.8370C>G p.V2790= | Silent (SNP) | VAF 278/593 reads (47%) | catalogued as COSV100634072; called by muse, mutect2, varscan2
- SCN4A | c.4788C>T p.I1596= | Silent (SNP) | VAF 274/708 reads (39%) | catalogued as COSV71127951; called by muse, mutect2, varscan2
- SHANK1 | c.108C>T p.G36= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1229642336, COSV53250608; called by muse, mutect2, varscan2
- SIRPA | c.267G>T p.R89= | Silent (SNP) | VAF 191/493 reads (39%) | catalogued as COSV100605322; called by muse, mutect2, varscan2
- SKAP1 | c.417C>A p.L139= | Silent (SNP) | VAF 58/145 reads (40%) | called by muse, mutect2, varscan2
- SLC10A2 | c.672C>T p.P224= | Silent (SNP) | VAF 217/534 reads (41%) | called by muse, varscan2
- SLC13A5 | c.327C>A p.I109= | Silent (SNP) | VAF 95/233 reads (41%) | called by muse, mutect2, varscan2
- SLC22A12 | c.1143C>T p.L381= | Silent (SNP) | VAF 188/463 reads (41%) | called by muse, mutect2, varscan2
- SPATA21 | c.276G>T p.V92= | Silent (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- SULT2B1 | c.546C>T p.G182= (on ENST00000201586 / NM_177973.2; = p.G167= on NM_004605.2) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs746998782, COSV52375415; called by muse, mutect2, varscan2
- TERT | c.417G>T p.L139= | Silent (SNP) | VAF 132/330 reads (40%) | called by muse, mutect2, varscan2
- TNNI3 | c.543C>A p.T181= | Silent (SNP) | VAF 155/328 reads (47%) | catalogued as COSV52573370; called by muse, mutect2, varscan2
- TRIM77 | c.780G>T p.L260= | Silent (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- UQCR11 | c.69A>G p.T23= | Silent (SNP) | VAF 91/141 reads (65%) | catalogued as rs775054289; called by muse, mutect2, varscan2
- VENTX | c.255G>A p.E85= | Silent (SNP) | VAF 63/207 reads (30%) | catalogued as rs1331901071; called by muse, mutect2, varscan2
- XKR4 | c.1758C>A p.R586= | Silent (SNP) | VAF 89/206 reads (43%) | called by muse, mutect2, varscan2
- ZER1 | c.48C>T p.F16= | Silent (SNP) | VAF 108/287 reads (38%) | called by muse, mutect2, varscan2
- AC008592.1 | chr5:95858870 G>T | 5'Flank (SNP) | VAF 37/57 reads (65%) | called by muse, mutect2, varscan2
- AC021218.1 | n.893G>T | RNA (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- AC074141.1 | n.2291G>A | RNA (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.987+76G>T | Intron (SNP) | VAF 164/243 reads (67%) | called by muse, mutect2, varscan2
- ADCY3 | c.1197-528C>T | Intron (SNP) | VAF 30/81 reads (37%) | catalogued as rs78927940; called by muse, mutect2, varscan2
- AP004607.5 | n.113G>C | RNA (SNP) | VAF 31/129 reads (24%) | called by muse, varscan2
- ASB10 | chr7:151187412 C>A | 5'Flank (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*2706G>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- C1orf220 | n.94G>T | RNA (SNP) | VAF 48/130 reads (37%) | called by muse, varscan2
- CA2 | c.-20C>G | 5'UTR (SNP) | VAF 148/409 reads (36%) | called by muse, mutect2, varscan2
- CCDC74B | c.295+318C>A | Intron (SNP) | VAF 42/62 reads (68%) | called by mutect2, varscan2
- CD163 | c.1735+47G>T | Intron (SNP) | VAF 168/354 reads (47%) | catalogued as COSV100775603; called by muse, mutect2, varscan2
- CEP170P1 | n.1873G>T | RNA (SNP) | VAF 203/265 reads (77%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+70C>A | Intron (SNP) | VAF 86/121 reads (71%) | catalogued as COSV54566198; called by muse, mutect2, varscan2
- CHRNB1 | c.244-28G>T | Intron (SNP) | VAF 114/285 reads (40%) | called by muse, mutect2, varscan2
- DBF4B | c.1189+352del | Intron (DEL) | VAF 73/201 reads (36%) | called by mutect2, pindel, varscan2
- DBNL | c.*2055C>T | 3'UTR (SNP) | VAF 178/448 reads (40%) | called by muse, mutect2, varscan2
- DCHS2 | n.7512G>C | RNA (SNP) | VAF 63/95 reads (66%) | called by muse, mutect2, varscan2
- EFHC1 | c.*1443G>T | 3'UTR (SNP) | VAF 240/636 reads (38%) | called by mutect2, varscan2
- FAM157A | chr3:198167684 G>A | 5'Flank (SNP) | VAF 105/164 reads (64%) | called by muse, mutect2, varscan2
- GABBR1 | c.*53G>T | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- GPR176 | c.173-21884C>A | Intron (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- GSDMD | c.579+114C>T | Intron (SNP) | VAF 51/109 reads (47%) | catalogued as rs1246254263; called by muse, mutect2, varscan2
- GUSBP10 | n.203G>T | RNA (SNP) | VAF 64/149 reads (43%) | catalogued as rs142310593; called by muse, mutect2, varscan2
- HAX1 | c.556+17G>T | Intron (SNP) | VAF 252/661 reads (38%) | called by muse, mutect2, varscan2
- HBB | c.93-18C>G | Intron (SNP) | VAF 205/299 reads (69%) | called by muse, mutect2, varscan2
- HNF4A | c.115+1105C>A | Intron (SNP) | VAF 124/243 reads (51%) | called by muse, mutect2, varscan2
- HOXA2 | c.391+173G>A | Intron (SNP) | VAF 50/183 reads (27%) | called by muse, mutect2, varscan2
- HYDIN | c.382-95G>T | Intron (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- ITGA4 | c.*2451T>C | 3'UTR (SNP) | VAF 44/66 reads (67%) | called by muse, mutect2, varscan2
- LINC02551 | n.1315G>T | RNA (SNP) | VAF 75/234 reads (32%) | called by muse, mutect2, varscan2
- ME3 | c.183+49C>T | Intron (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- MIB1 | c.1829+6051A>T | Intron (SNP) | VAF 67/93 reads (72%) | called by muse, mutect2, varscan2
- MMP9 | c.1901+12C>A | Intron (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- NCSTN | chr1:160343359 G>T | 5'Flank (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- NDRG2 | c.468+67A>T | Intron (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2
- OSCAR | c.*349G>T | 3'UTR (SNP) | VAF 56/133 reads (42%) | catalogued as COSV52928583; called by muse, mutect2, varscan2
- PCLAF | c.290+2967C>T | Intron (SNP) | VAF 54/186 reads (29%) | called by muse, mutect2, varscan2
- POLN | c.2309-9G>T | Intron (SNP) | VAF 130/192 reads (68%) | called by muse, mutect2, varscan2
- PPFIA2 | c.303+78818G>T | Intron (SNP) | VAF 98/206 reads (48%) | called by muse, mutect2, varscan2
- PTPRD | c.541+168C>A | Intron (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- RPL35 | c.-34G>T | 5'UTR (SNP) | VAF 52/73 reads (71%) | catalogued as rs1205670152; called by muse, mutect2, varscan2
- SECISBP2 | chr9:89363777 T>A | 3'Flank (SNP) | VAF 150/207 reads (72%) | called by muse, mutect2, varscan2
- SERPINA13P | n.296C>A | RNA (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- TARM1 | chr19:54081334 G>T | 5'Flank (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- TCP10L3 | n.625C>T | RNA (SNP) | VAF 31/132 reads (23%) | catalogued as COSV100832931; called by muse, mutect2, varscan2
- TGM2 | c.1616-96G>A | Intron (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- TPCN1 | c.-97G>T | 5'UTR (SNP) | VAF 57/206 reads (28%) | called by muse, mutect2, varscan2
- TSPAN9 | c.648+88G>T | Intron (SNP) | VAF 174/522 reads (33%) | called by muse, mutect2, varscan2
- WDFY4 | c.-14T>A | 5'UTR (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
